Somatic mutation profile of tumor specimen 0DQ80U from CCDI case PBCEUP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Subependymal giant cell astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (448 days).
Specimen 0DQ80U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49e7fd5a-5d3b-4728-951e-63c9fb6c87d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7WI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebbf1091-337c-4f1c-9397-18d967b3ad9b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.5227C>T p.R1743W | Missense Mutation (SNP) | VAF 63/447 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs45517412, CM052391, CM091157, COSV51918349; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- PNPLA8 | c.1207-88G>T | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
